Surgical pathology report (de-identified scan), TCGA case TCGA-FG-5965, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-5965-02A (Recurrent Tumor).

SURGICAL PATHOLOGY REPORT

Race: CAUCASIAN

DOB/Sex: F

FINAL DIAGNOSIS

A, B. RIGHT FRONTAL LOBE OF BRAIN, LESION, BIOPSY AND REMOVAL:
-- ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III).

Note: The tumor demonstrates prominent microvascular proliferation and focal coagulative necrosis without pseudo-palisading. Although mitotic figures are inconspicuous, there is a population of polyploid appearing tumor cells possibly representing abortive mitotic activity.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Microscopic: Oligoastrocytoma.

1C5-0-3

Oligoastrocytoma, anaplastic 9382/3

Site: brain, frontal lobe C71.1

hw
10/23/12

Clinical History:

Right frontal brain mass

Specimens Submitted As:

A:RIGHT FRONTAL LESION

B:RIGHT FRONTAL LESION

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number, and "right frontal lesion" are multiple pink-tan soft tissue fragments, 1 x 0.5 x 0.2 cm in aggregate. The entire specimen is submitted for frozen. The specimen is submitted entirely in one cassette.

B: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "right frontal lesion perm", are multiple pink-tan irregular soft cerebriform tissue fragments measuring 4.0 x 3.0 x 2.1 cm in aggregate. On section, the fragments are tan-gray. Also received is one tan-gray, glistening fragment of dura measuring 2.2 x 1.8 x 0.4 cm. Representative sections are submitted in three cassettes.

(recurrence 1 of 2)

L66 Cecur

hw
10/23/12

Source: NCI Genomic Data Commons file 059ea9b1-cae5-4d89-9bbc-db80b08c0333 (TCGA-FG-5965.78FA386B-5BF9-4869-8A1F-931B372DBAE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).